Somatic mutation profile of tumor specimen C3L-00932-01 (aliquot CPT0027120009) from CPTAC case C3L-00932, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.1 years (24,510 days).
Specimen C3L-00932-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05a06878-78a4-4aea-8be5-c1b27c50b456.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00932-31 (Blood Derived Normal), aliquot CPT0027180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d240ba88-76ab-4d4e-99dc-1e134007cf70

The open-access MAF lists 208 somatic variants for this specimen: 137 protein-altering or splice-affecting, 44 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 44, Intron 14, 5'UTR 6, Frame Shift Del 5, Nonsense Mutation 4, 3'UTR 4, Splice Site 3, 3'Flank 2, Splice Region 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 11/92 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB2 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212449443; called by muse, mutect2
- ADNP2 | c.2837G>C p.S946T | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1262496032; called by muse, mutect2
- AKAP1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1422441599, COSV58469590; called by muse, mutect2
- ARHGAP24 | c.490C>T p.R164* (on ENST00000395184 / NM_001025616.3; = p.R71* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 34/278 reads (12%) | catalogued as rs781623663; called by muse, varscan2
- BHLHE22 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58863271; called by muse, mutect2
- C4orf54 | c.3025A>G p.T1009A | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs1367644515; called by muse, mutect2
- CCL5 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs777737112; called by muse, mutect2
- CDH4 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs1309693430, COSV64671463; called by muse, mutect2
- COL18A1 | c.484del p.Q162Rfs*107 (on ENST00000359759 / NM_130444.3; = p.Q162Rfs*142 on NM_030582.4) | Frame Shift Del (DEL) | VAF 12/158 reads (8%) | catalogued as rs766977257; called by mutect2, pindel
- CRACD | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs772549120, COSV51730380, COSV99949016; called by muse, mutect2, varscan2
- CUL9 | c.7216A>G p.S2406G | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1301028492; called by muse, mutect2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs782381199; called by mutect2, pindel
- DCAF4 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs891332945; called by muse, mutect2
- DDX11 | c.1369+1G>A p.X457_splice | Splice Site (SNP) | VAF 15/408 reads (4%) | catalogued as rs1318749578; called by muse, mutect2
- EIF3A | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771764319, COSV64960575; called by muse, mutect2
- FGF14 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 22/575 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs868433062, COSV65951449; called by muse, mutect2
- FOXP4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1248213330; called by muse, mutect2, varscan2
- GANAB | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs370213372; called by muse, mutect2
- GRM5 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100551725; called by muse, mutect2
- HIF3A | c.1243C>A p.R415S (on ENST00000377670 / NM_152795.4; = p.R346S on NM_022462.4) | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV99355793; called by muse, mutect2
- HOXD8 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234134717, COSV100497135; called by muse, mutect2
- IGHG4 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 21/192 reads (11%) | catalogued as rs752177177; called by muse, mutect2, varscan2
- IGHV3-11 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.848); catalogued as rs782493248; called by muse, mutect2, varscan2
- ITGAL | c.3185G>A p.S1062N | Missense Mutation (SNP) | VAF 13/315 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV63323803; called by muse, mutect2
- KCTD8 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63586851; called by muse, mutect2
- KMT2D | c.16598G>A p.R5533Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1028780200, COSV56444899; called by muse, mutect2
- KRT31 | c.1178G>A p.C393Y | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV52434234, COSV99289795; called by muse, mutect2
- MYH3 | c.5330G>T p.S1777I | Missense Mutation (SNP) | VAF 30/646 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV56860936; called by muse, mutect2
- NEK8 | c.1693A>G p.S565G | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV52044234; called by muse, mutect2
- NPAS1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs1232687347; called by muse, mutect2, varscan2
- PCDHA13 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as rs782413139, COSV99166755; called by muse, mutect2
- PCDHB2 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 25/747 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.079); catalogued as COSV50564882; called by muse, mutect2
- PCNT | c.7609_7611del p.E2537del | In Frame Del (DEL) | VAF 20/252 reads (8%) | catalogued as rs761218984; called by mutect2, pindel
- PKD1 | c.6535G>A p.V2179I | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.351); catalogued as rs754761933, COSV51916191; called by muse, mutect2
- POLR1F | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1056489530, COSV55998033; called by muse, mutect2
- PRR33 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480747537; called by muse, mutect2
- RCAN1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568882410; called by muse, mutect2
- RELN | c.8077G>A p.G2693R | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs377549748; called by muse, mutect2, varscan2
- RELN | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs1238589028, COSV59022210; called by muse, mutect2
- SHROOM3 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs991755928; called by muse, mutect2
- SLC33A1 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63946692; called by muse, mutect2
- SOX17 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810843; called by muse, mutect2, varscan2
- SPTB | c.2570C>G p.T857R | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs1328144787; called by muse, mutect2
- TLN2 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as rs1337663070; called by muse, mutect2
- TLR9 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773699082, COSV100564405; called by mutect2, varscan2
- TMEM132B | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV54773216; called by muse, mutect2
- TMEM54 | c.268del p.L90Cfs*17 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | catalogued as rs1307577775; called by mutect2, pindel, varscan2
- TRPC6 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755825482, COSV60258857; called by muse, mutect2, varscan2
- TSHR | c.1309C>T p.L437F | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV53321610; called by muse, mutect2
- TSPYL2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as rs781875909; called by muse, mutect2
- VCL | c.877del p.X293_splice | Splice Site (DEL) | VAF 46/384 reads (12%) | catalogued as COSV99281006; called by mutect2, pindel, varscan2
- VIPR1 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.173); catalogued as rs1421242582; called by muse, mutect2
- ZFHX3 | c.7900G>A p.G2634R | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV51728461; called by muse, mutect2
- ADGRG4 | c.4979C>A p.P1660H | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- AGO2 | c.2264G>A p.G755D | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AR | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ARHGAP32 | c.921G>A p.Q307= | Splice Region (SNP) | VAF 37/221 reads (17%) | called by muse, mutect2, varscan2
- ARID1B | c.3857G>T p.G1286V | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCLAF3 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- CAPN15 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); called by muse, mutect2
- CASP10 | c.1264G>A p.A422T (on ENST00000272879 / NM_032974.5; = p.A379T on NM_001230.5) | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.229); called by muse, mutect2
- CCDC86 | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2
- CCT4 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 14/460 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CDC23 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- CEACAM18 | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2
- CGAS | c.768T>A p.N256K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2
- CLMN | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.038); called by muse, mutect2
- COL6A6 | c.2146A>G p.K716E | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- COL7A1 | c.4372C>T p.P1458S | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2
- CPLX4 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- DAG1 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2
- DBNL | c.1264C>A p.P422T (on ENST00000448521 / NM_001014436.3; = p.P423T on NM_014063.7) | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX58 | c.2198C>G p.A733G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH5 | c.7582G>A p.A2528T | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2
- DUSP26 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- EDC3 | c.1110T>A p.N370K | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2
- EEF2 | c.2515C>A p.R839S | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ELK1 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- ELMO2 | c.78+3A>G | Splice Region (SNP) | VAF 9/242 reads (4%) | called by muse, mutect2
- FBXL18 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO32 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FOXF1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 14/377 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FZR1 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- GABRG1 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GIT2 | c.1028C>T p.A343V (on ENST00000355312 / NM_057169.5; = p.A345V on NM_014776.5) | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- GMIP | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- GPR135 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2
- HCFC1 | c.4283G>C p.G1428A | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HP | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 22/600 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- ITGA9 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- KBTBD2 | c.1238G>C p.S413T | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); called by muse, mutect2
- KIF13A | c.5207C>T p.T1736I | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KRT84 | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.562); called by muse, mutect2
- LAMB3 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPIN2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 19/515 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2
- LRRC52 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2
- MAGEB6B | c.175T>G p.S59A | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- MCF2L | c.1356del p.L453Cfs*16 (on ENST00000375608; = p.L421Cfs*16 on NM_024979.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/180 reads (8%) | called by mutect2, pindel
- MYO9B | c.2745G>T p.E915D | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2
- NEFL | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 24/681 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2
- NLGN3 | c.914-1G>T p.X305_splice (on ENST00000358741 / NM_181303.2; = p.X285_splice on NM_018977.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 19/255 reads (7%) | called by muse, mutect2
- NOTCH3 | c.3538G>A p.G1180S | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5P3 | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- OTX1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.033); called by muse, mutect2
- PADI4 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PARP1 | c.786G>T p.K262N | Missense Mutation (SNP) | VAF 28/599 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2
- PDZD4 | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.013); called by muse, mutect2
- PKHD1 | c.1162T>C p.Y388H | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POMT1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 33/567 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.036); called by muse, mutect2
- PPAN-P2RY11 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2
- QRICH2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2
- RIN2 | c.897T>A p.H299Q (on ENST00000255006 / NM_001242581.1; = p.H250Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); called by muse, mutect2
- SAMD11 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCOC | c.56T>C p.M19T | Missense Mutation (SNP) | VAF 14/389 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- SERINC2 | c.1201C>T p.H401Y (on ENST00000373709 / NM_178865.5; = p.H405Y on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.072); called by muse, mutect2
- SETMAR | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2
- SLC4A11 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 19/567 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2
- SP4 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2
- SRC | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- SRI | c.256A>T p.M86L | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM44 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.178); called by muse, mutect2
- TMEM45B | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNRC18 | c.8833T>C p.Y2945H | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAV8-4 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 19/414 reads (5%) | called by muse, mutect2
- TRIOBP | c.5756G>T p.G1919V (on ENST00000644935 / NM_001039141.3; = p.G206V on NM_007032.5) | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2
- TRRAP | c.3688A>T p.I1230F | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC32 | c.241T>C p.Y81H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TYR | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- UBA1 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- VPS13D | c.6047C>T p.A2016V | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.43); called by muse, mutect2
- WASHC2A | c.2263T>A p.F755I | Missense Mutation (SNP) | VAF 18/355 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.073); called by muse, mutect2
- WWP2 | c.804C>A p.N268K | Missense Mutation (SNP) | VAF 19/353 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2
- ZNF169 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF292 | c.3356T>C p.M1119T | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ZNF808 | c.2120A>G p.Y707C | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZNF865 | c.594del p.A199Rfs*18 | Frame Shift Del (DEL) | VAF 7/84 reads (8%) | called by mutect2, pindel
- ACTL9 | c.580C>T p.L194= | Silent (SNP) | VAF 11/206 reads (5%) | called by muse, mutect2
- ARHGAP35 | c.3723C>A p.T1241= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- CBLN4 | c.150G>A p.T50= | Silent (SNP) | VAF 12/366 reads (3%) | catalogued as rs1295945825; called by muse, mutect2
- CCDC189 | c.426A>C p.S142= | Silent (SNP) | VAF 27/554 reads (5%) | called by muse, mutect2
- CCDC40 | c.693G>A p.V231= | Silent (SNP) | VAF 26/614 reads (4%) | called by muse, mutect2
- COL1A1 | c.3645C>T p.Y1215= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as COSV56802479; called by muse, mutect2
- CSMD1 | c.6582G>A p.T2194= (on ENST00000520002; = p.T2193= on NM_033225.6) | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs1055657160; called by muse, mutect2
- FANCI | c.3237G>A p.T1079= (on ENST00000310775 / NM_001376911.1; = p.T1019= on NM_018193.3) | Silent (SNP) | VAF 34/662 reads (5%) | catalogued as rs767103109; ClinVar: uncertain significance; called by muse, mutect2
- FAT3 | c.2541T>C p.G847= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- G6PD | c.990C>T p.R330= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as rs782064465, COSV63704854, COSV63704918; called by muse, mutect2
- GLI3 | c.1284C>T p.D428= | Silent (SNP) | VAF 19/510 reads (4%) | called by muse, mutect2
- GLS2 | c.651G>A p.L217= | Silent (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- ITPR3 | c.1305C>T p.P435= | Silent (SNP) | VAF 11/228 reads (5%) | catalogued as rs1405155961, COSV65409399; called by muse, mutect2
- KCND3 | c.1704C>T p.R568= | Silent (SNP) | VAF 22/592 reads (4%) | catalogued as rs1457451483; called by muse, mutect2
- KCTD12 | c.822C>T p.F274= | Silent (SNP) | VAF 41/343 reads (12%) | catalogued as rs1381337868; called by muse, mutect2, varscan2
- KRT12 | c.861C>T p.D287= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as rs779289274, COSV52431683; called by muse, mutect2
- MAML1 | c.252G>A p.A84= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- ME2 | c.1713A>G p.E571= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs1237605567; called by muse, mutect2
- MTG2 | c.513C>T p.A171= | Silent (SNP) | VAF 14/424 reads (3%) | catalogued as rs981532922, COSV63694363; called by muse, mutect2
- MUC12 | c.13446C>T p.T4482= (on ENST00000379442; = p.T4339= on NM_001164462.1) | Silent (SNP) | VAF 57/472 reads (12%) | catalogued as rs1159304960; called by muse, mutect2, varscan2
- MYH7 | c.708C>T p.V236= | Silent (SNP) | VAF 22/592 reads (4%) | called by muse, mutect2
- NCOA3 | c.2043G>A p.K681= | Silent (SNP) | VAF 17/226 reads (8%) | catalogued as COSV100507275, COSV100508611; called by muse, mutect2
- NCSTN | c.147C>A p.P49= | Silent (SNP) | VAF 16/440 reads (4%) | catalogued as COSV54106132; called by muse, mutect2
- NISCH | c.1509G>A p.Q503= | Silent (SNP) | VAF 18/320 reads (6%) | catalogued as COSV100617320; called by muse, mutect2
- NKX6-2 | c.486G>A p.A162= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- NOBOX | c.666C>T p.A222= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV56197235; called by muse, mutect2, varscan2
- PCDHB12 | c.651C>T p.G217= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs561631495, COSV53393325; called by muse, mutect2
- POTEC | c.372C>T p.D124= | Silent (SNP) | VAF 24/797 reads (3%) | catalogued as rs1209528281, COSV62805457; called by muse, mutect2
- PRNP | c.564G>T p.T188= | Silent (SNP) | VAF 26/491 reads (5%) | catalogued as COSV65173715; called by muse, mutect2
- S100A8 | c.112C>T p.L38= | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- SIGLEC1 | c.2211C>T p.G737= | Silent (SNP) | VAF 20/514 reads (4%) | catalogued as COSV52458792; called by muse, mutect2
- SMARCD3 | c.705G>A p.T235= (on ENST00000262188 / NM_001003801.2; = p.T222= on NM_003078.4) | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs140296892; called by muse, mutect2, varscan2
- STK10 | c.879C>T p.F293= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV51572770; called by muse, mutect2
- SYNM | c.4620G>A p.S1540= (on ENST00000336292 / NM_145728.3; = p.S1228= on NM_015286.6) | Silent (SNP) | VAF 12/354 reads (3%) | catalogued as rs868913251; called by muse, mutect2
- TAT | c.1179G>A p.T393= | Silent (SNP) | VAF 35/345 reads (10%) | catalogued as rs760896128; called by muse, mutect2, varscan2
- TECPR2 | c.3216G>A p.Q1072= | Silent (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
- TERT | c.523C>T p.L175= | Silent (SNP) | VAF 24/576 reads (4%) | called by muse, mutect2
- TEX15 | c.6846G>A p.G2282= (on ENST00000256246; = p.G2665= on NM_001350162.2) | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- TLN2 | c.1026C>A p.R342= | Silent (SNP) | VAF 33/272 reads (12%) | catalogued as COSV60891119; called by muse, mutect2, varscan2
- TMCC2 | c.459G>A p.Q153= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- UCKL1 | c.735C>T p.R245= | Silent (SNP) | VAF 26/320 reads (8%) | catalogued as rs1357318977, COSV62402947; called by muse, mutect2
- UTP11 | c.600C>T p.N200= | Silent (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- ZHX3 | c.453G>T p.V151= | Silent (SNP) | VAF 14/262 reads (5%) | catalogued as COSV58386059; called by muse, mutect2
- ZNF444 | c.591C>T p.H197= | Silent (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- ABI3BP | c.1577-9246C>A | Intron (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- AC244197.3 | c.-1881C>G | 5'UTR (SNP) | VAF 41/304 reads (13%) | called by muse, mutect2, varscan2
- AHSG | c.573+9_573+10del | Intron (DEL) | VAF 35/292 reads (12%) | called by mutect2, pindel, varscan2
- AKT2 | c.639+126G>A | Intron (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
- CDK20 | c.*61G>A | 3'UTR (SNP) | VAF 17/288 reads (6%) | catalogued as rs936847500; called by muse, mutect2
- CHMP1A | c.382-46dup | Intron (INS) | VAF 10/116 reads (9%) | called by mutect2, pindel
- CHRNA4 | c.*3276G>A | 3'UTR (SNP) | VAF 16/438 reads (4%) | catalogued as rs1433570523; called by muse, mutect2
- CLK3 | chr15:74635109 C>T | 3'Flank (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- FAM174C | c.*111C>A | 3'UTR (SNP) | VAF 16/312 reads (5%) | called by muse, mutect2
- GZMA | c.-10A>C | 5'UTR (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- HARS1 | chr5:140673417 G>A | 3'Flank (SNP) | VAF 24/448 reads (5%) | called by muse, mutect2
- IKBKE | c.1836-268G>A | Intron (SNP) | VAF 6/108 reads (6%) | catalogued as rs782686002; called by muse, mutect2
- KIF7 | c.2593-22G>A | Intron (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- MDGA2 | c.281-41425C>T | Intron (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- MPPED1 | c.-21C>T | 5'UTR (SNP) | VAF 30/188 reads (16%) | catalogued as rs746196123; called by muse, mutect2, varscan2
- NPNT | c.172+14237G>A | Intron (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- OCRL | c.-88C>T | 5'UTR (SNP) | VAF 12/330 reads (4%) | catalogued as rs1260139768; called by muse, mutect2
- PHGDH | c.356+1395C>T | Intron (SNP) | VAF 42/421 reads (10%) | catalogued as rs1275017283; called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1168G>A | RNA (SNP) | VAF 32/414 reads (8%) | catalogued as rs772082817; called by muse, mutect2
- RPL9 | c.162+138G>A | Intron (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2
- SERTAD4 | c.-18+729G>A | Intron (SNP) | VAF 30/568 reads (5%) | catalogued as rs1470785747; called by muse, mutect2
- SLC22A5 | c.-16G>T | 5'UTR (SNP) | VAF 13/212 reads (6%) | called by muse, mutect2
- SLC26A6 | c.1894-9G>C | Intron (SNP) | VAF 5/70 reads (7%) | catalogued as rs1380487819; called by muse, mutect2
- SLC29A3 | c.*657del | 3'UTR (DEL) | VAF 16/202 reads (8%) | called by mutect2, pindel
- SPTAN1 | c.4890+51T>C | Intron (SNP) | VAF 18/243 reads (7%) | called by muse, mutect2
- UXT | c.-10+12G>A | Intron (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- VPS11 | c.-375C>T | 5'UTR (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
